Somatic mutation profile of tumor specimen TCGA-21-1081-01A (aliquot TCGA-21-1081-01A-01W-0782-08) from TCGA case TCGA-21-1081, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.7 years (25,440 days).
Specimen TCGA-21-1081-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a023300d-b284-4bba-ab92-45449fb3439e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1081-10B (Blood Derived Normal), aliquot TCGA-21-1081-10B-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/395344da-bd68-4b1f-a02e-0e31115f764e

The open-access MAF lists 258 somatic variants for this specimen: 198 protein-altering or splice-affecting, 51 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 171, Silent 51, Nonsense Mutation 14, Intron 6, Frame Shift Ins 6, Splice Site 3, Frame Shift Del 2, 5'Flank 2, Splice Region 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INTU | c.396del p.N132Kfs*11 | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | catalogued as rs1553970289, CD166923; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- AC100868.1 | c.1509C>A p.F503L | Missense Mutation (SNP) | VAF 155/672 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0.014); catalogued as COSV51844117; called by muse, mutect2, varscan2
- ADAMTS19 | c.1703C>A p.T568K | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV50752175; called by muse, mutect2, varscan2
- ADGRG7 | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 47/294 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs144717099, COSV99841095; called by muse, mutect2, varscan2
- AMOTL2 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as COSV51439302; called by muse, mutect2, varscan2
- APCS | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54817288; called by muse, mutect2, varscan2
- ARHGAP35 | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 71/281 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV68329079; called by muse, mutect2, varscan2
- ARHGAP5 | c.3080G>A p.C1027Y | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.081); catalogued as rs1249616392; called by muse, mutect2
- ARHGEF11 | c.3949G>A p.A1317T | Missense Mutation (SNP) | VAF 94/288 reads (33%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1201926129; called by muse, varscan2
- ATP11A | c.2999G>A p.G1000E | Missense Mutation (SNP) | VAF 43/1079 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.391); catalogued as rs1479095052, COSV52113176; called by muse, mutect2
- ATP11C | c.1645C>G p.R549G | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59559449, COSV59565145; called by muse, mutect2, varscan2
- BLNK | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 30/486 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV56411479, COSV99813569; called by muse, mutect2
- BRINP1 | c.216C>A p.Y72* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV56301641; called by muse, mutect2, varscan2
- C10orf88 | c.739G>T p.G247* | Nonsense Mutation (SNP) | VAF 100/221 reads (45%) | catalogued as COSV64404015; called by muse, mutect2, varscan2
- C12orf66 | c.146dup p.S50Qfs*50 | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | catalogued as rs771314426; called by pindel, varscan2
- C2CD5 | c.1135A>T p.I379F | Missense Mutation (SNP) | VAF 306/444 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61724913; called by muse, varscan2
- C2CD5 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as rs1384283126, COSV61724922; called by muse, mutect2, varscan2
- CASZ1 | c.1508C>T p.T503M | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59735448; called by mutect2, varscan2
- CCDC115 | c.308G>T p.R103M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV52091851; called by muse, mutect2, varscan2
- CCDC116 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.188); catalogued as rs771117152, COSV53037972; called by muse, mutect2, varscan2
- CCDC39 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs780264719, COSV56477777; ClinVar: uncertain significance; called by mutect2, varscan2
- CD3E | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 159/705 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as rs201739383, COSV62345365; called by muse, mutect2, varscan2
- CDH16 | c.1686dup p.K563Qfs*41 | Frame Shift Ins (INS) | VAF 8/80 reads (10%) | catalogued as rs776664434; called by pindel, varscan2
- CDK14 | c.265C>G p.Q89E (on ENST00000380050 / NM_001287135.2; = p.Q71E on NM_012395.3) | Missense Mutation (SNP) | VAF 130/331 reads (39%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.68); catalogued as COSV56036668; called by muse, mutect2, varscan2
- CLPTM1L | c.1276A>T p.K426* | Nonsense Mutation (SNP) | VAF 38/80 reads (48%) | catalogued as COSV57990761; called by muse, varscan2
- CLSTN2 | c.2519C>T p.S840F | Missense Mutation (SNP) | VAF 100/1100 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs753704000, COSV71718479; called by muse, mutect2
- CPS1 | c.3888G>T p.L1296F | Missense Mutation (SNP) | VAF 54/303 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.676); catalogued as COSV51811972; called by muse, mutect2, varscan2
- CPVL | c.242A>G p.N81S | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771212555, COSV55303374; called by muse, mutect2, varscan2
- CREBBP | c.3893A>G p.Y1298C | Missense Mutation (SNP) | VAF 47/245 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.707); catalogued as rs773159964, COSV52125779; called by muse, mutect2, varscan2
- CREBBP | c.2827C>T p.Q943* | Nonsense Mutation (SNP) | VAF 220/424 reads (52%) | catalogued as CD021194, COSV52122968; called by muse, mutect2, varscan2
- CRIM1 | c.2656A>G p.I886V | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.891); catalogued as rs748998611, COSV54865147; called by muse, mutect2, varscan2
- CRYM | c.512A>T p.K171I | Missense Mutation (SNP) | VAF 159/373 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV54831628; called by muse, mutect2, varscan2
- CUX1 | c.2849G>C p.R950P | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52898145, COSV52901564; called by muse, mutect2, varscan2
- CXCR4 | c.842A>G p.H281R | Missense Mutation (SNP) | VAF 129/713 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.078); catalogued as COSV54013044; called by muse, mutect2, varscan2
- CYP24A1 | c.937A>C p.K313Q | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as COSV53774806; called by muse, mutect2, varscan2
- DCANP1 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs376193776; called by muse, varscan2
- DNAH8 | c.10228C>A p.Q3410K | Missense Mutation (SNP) | VAF 164/277 reads (59%) | SIFT tolerated (0.93); PolyPhen benign (0.012); catalogued as COSV59451081; called by muse, mutect2, varscan2
- DOCK10 | c.4076G>A p.R1359K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (1); PolyPhen probably damaging (0.977); catalogued as COSV51412465; called by muse, mutect2, varscan2
- DOCK4 | c.3677A>G p.Y1226C | Missense Mutation (SNP) | VAF 96/153 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69854662; called by muse, mutect2, varscan2
- ELP5 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 74/102 reads (73%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV59708761; called by muse, mutect2, varscan2
- EVX1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV56085103; called by muse, mutect2, varscan2
- FAT1 | c.6939A>C p.E2313D | Missense Mutation (SNP) | VAF 68/113 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0.307); catalogued as COSV71674427; called by muse, mutect2, varscan2
- FBXO28 | c.713T>G p.V238G | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs754071147, COSV64800572; called by muse, mutect2, varscan2
- FNTA | c.1136A>G p.Q379R | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as rs756611552, COSV56490172; called by mutect2, varscan2
- FOXH1 | c.851T>C p.I284T | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV56761229; called by muse, mutect2
- FRY | c.8027C>A p.A2676D | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV66571189; called by muse, mutect2, varscan2
- GABRA2 | c.1223A>G p.K408R | Missense Mutation (SNP) | VAF 179/353 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.069); catalogued as COSV62913537; called by muse, mutect2, varscan2
- GAD1 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60151605, COSV60152627; called by muse, mutect2, varscan2
- GIMAP1 | c.131G>C p.G44A | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56188383; called by muse, mutect2, varscan2
- GUCY2C | c.3183G>C p.L1061F | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.059); catalogued as COSV99663536; called by muse, mutect2
- GUSB | c.1796C>T p.T599M | Missense Mutation (SNP) | VAF 123/433 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as rs765983374, COSV59222148; called by muse, mutect2, varscan2
- HCCS | c.190G>T p.V64L | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV58239183; called by muse, mutect2, varscan2
- HCRTR2 | c.762+2T>A p.X254_splice | Splice Site (SNP) | VAF 37/103 reads (36%) | catalogued as COSV63796171; called by muse, mutect2, varscan2
- HECTD4 | c.13100dup p.D4368Rfs*44 | Frame Shift Ins (INS) | VAF 15/120 reads (13%) | catalogued as rs746492036; called by mutect2, varscan2
- HLTF | c.2452G>A p.A818T | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV59501086; called by mutect2, varscan2
- HNRNPA3 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV66820681, COSV66820724; called by muse, mutect2, varscan2
- INSC | c.1546C>T p.L516F | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1171610072; called by mutect2, varscan2
- ITGB4 | c.1764C>T p.G588= | Splice Region (SNP) | VAF 31/86 reads (36%) | catalogued as COSV52326846; called by muse, mutect2, varscan2
- ITSN1 | c.2488C>T p.R830C | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as rs768901601, COSV66082643; called by muse, mutect2, varscan2
- KCNH7 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.47); catalogued as COSV59798742; called by muse, mutect2, varscan2
- KCNK2 | c.1066C>T p.Q356* (on ENST00000444842 / NM_001017425.3; = p.Q341* on NM_014217.4) | Nonsense Mutation (SNP) | VAF 23/140 reads (16%) | catalogued as COSV67206474; called by muse, mutect2, varscan2
- KCTD10 | c.536A>G p.D179G | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57327103; called by muse, mutect2, varscan2
- KCTD9 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1448423271, COSV55339685; called by muse, varscan2
- KDM5A | c.1658A>G p.Y553C | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV66991302; called by muse, mutect2, varscan2
- KIAA0232 | c.325A>G p.K109E | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56925782; called by muse, mutect2, varscan2
- KIF9 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 82/141 reads (58%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV55520023; called by muse, varscan2
- KRTAP12-4 | c.56G>A p.C19Y | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs376121988, COSV59964804; called by mutect2, varscan2
- LAMA1 | c.5980C>T p.L1994F | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.394); catalogued as COSV67538156; called by muse, mutect2
- LCA5 | c.369G>C p.Q123H | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0.054); catalogued as COSV63971615, COSV63972540; called by muse, mutect2, varscan2
- MAVS | c.402A>T p.R134S | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV63927042; called by muse, mutect2
- MGAT1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | PolyPhen probably damaging (0.986); catalogued as COSV57134243; called by muse, mutect2, varscan2
- MROH1 | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1196845588; called by muse, mutect2, varscan2
- MTBP | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV59963426; called by muse, mutect2, varscan2
- MYH1 | c.4235A>T p.N1412I | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV56849600; called by muse, mutect2, varscan2
- MYO16 | c.4971dup p.A1658Rfs*45 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | catalogued as rs768115108; called by pindel, varscan2
- MYO1A | c.722C>G p.A241G | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as COSV55654457; called by muse, varscan2
- MYT1L | c.1144C>A p.L382I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.996); catalogued as COSV67721601; called by muse, mutect2, varscan2
- NEB | c.4825C>T p.Q1609* | Nonsense Mutation (SNP) | VAF 36/392 reads (9%) | catalogued as rs777103145; called by muse, mutect2
- NLGN1 | c.808C>A p.L270M | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64335336; called by muse, mutect2, varscan2
- NLRP11 | c.1492C>A p.L498I | Missense Mutation (SNP) | VAF 97/364 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV64087605; called by muse, mutect2, varscan2
- NLRP13 | c.267C>A p.F89L | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as COSV61622136, COSV61622342; called by muse, mutect2, varscan2
- OAZ3 | c.282C>G p.D94E | Missense Mutation (SNP) | VAF 110/374 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100162391; called by muse, varscan2
- OR4C11 | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 115/153 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56353580; called by muse, mutect2, varscan2
- OR4C6 | c.289A>G p.T97A | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.011); catalogued as COSV58604314; called by muse, mutect2, varscan2
- OR52B4 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV68769017; called by muse, mutect2, varscan2
- OR5H14 | c.903C>A p.F301L | Missense Mutation (SNP) | VAF 44/252 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71194010; called by muse, varscan2
- OR5H6 | c.908C>G p.P303R (on ENST00000642105; = p.P287R on NM_001005479.2) | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV101051739, COSV67351583; called by muse, mutect2, varscan2
- OR6K3 | c.149T>A p.I50N (on ENST00000368146; = p.I34N on NM_001005327.2) | Missense Mutation (SNP) | VAF 73/351 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV63745729; called by muse, mutect2, varscan2
- OR6K6 | c.1012G>T p.A338S (on ENST00000368144; = p.A314S on NM_001005184.1) | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as rs760406673, COSV63744271; called by muse, mutect2, varscan2
- OR9A2 | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 40/461 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV63306667; called by muse, mutect2
- OSR2 | c.371C>A p.A124D | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52557178; called by muse, varscan2
- PCARE | c.1570C>A p.P524T | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV59055211; called by muse, mutect2, varscan2
- PDE4DIP | c.3029G>A p.R1010K | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs782670958, COSV57699093; called by muse, mutect2, varscan2
- PDE4DIP | c.3030G>T p.R1010S | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.167); catalogued as COSV57699079, COSV57731045; called by muse, mutect2, varscan2
- PDIA5 | c.1444G>A p.G482R | Missense Mutation (SNP) | VAF 74/436 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1036954941; called by muse, mutect2, varscan2
- PGLYRP2 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs780886152, COSV52994408; called by muse, mutect2, varscan2
- PHYH | c.597C>G p.I199M | Missense Mutation (SNP) | VAF 94/154 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1407156746, COSV53816160; called by muse, mutect2, varscan2
- PIK3CD | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV63129068; called by muse, varscan2
- PKNOX2 | c.571A>G p.I191V | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV53546902; called by muse, mutect2, varscan2
- PLIN4 | c.2127G>C p.K709N (on ENST00000301286; = p.K724N on NM_001367868.2) | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs370698276; called by muse, mutect2, varscan2
- PLXNA3 | c.5309C>T p.S1770L | Missense Mutation (SNP) | VAF 83/154 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63755496; called by mutect2, varscan2
- PLXNA4 | c.4165C>T p.L1389F | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1562894072, COSV58130856; called by muse, mutect2, varscan2
- PLXNA4 | c.1744T>A p.Y582N | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV58130876; called by muse, mutect2, varscan2
- PPP1R3A | c.280T>A p.L94I | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.615); catalogued as COSV52883939; called by muse, mutect2, varscan2
- PPP2R2C | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs781182513, COSV59444662; called by muse, varscan2
- PRKN | c.599A>C p.H200P | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV58230489; called by muse, mutect2, varscan2
- PRSS22 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50720886, COSV50721856; called by muse, mutect2, varscan2
- PSG8 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 96/772 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV60612328; called by muse, mutect2, varscan2
- PXDNL | c.1505A>T p.Q502L | Missense Mutation (SNP) | VAF 34/562 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV62488616; called by muse, mutect2
- RALGAPB | c.1142dup p.H382Tfs*2 | Frame Shift Ins (INS) | VAF 20/161 reads (12%) | catalogued as rs756557178; called by mutect2, varscan2
- RASSF9 | c.1141A>G p.R381G | Missense Mutation (SNP) | VAF 181/270 reads (67%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV63434042; called by muse, mutect2, varscan2
- RHAG | c.789C>A p.H263Q | Missense Mutation (SNP) | VAF 175/577 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV57704643; called by muse, mutect2, varscan2
- RIPK1 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99454799; called by muse, mutect2, varscan2
- ROR2 | c.2565G>A p.M855I | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs140727324, COSV100995890; called by mutect2, varscan2
- RP1 | c.1970T>G p.L657R | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.174); catalogued as COSV55118137; called by muse, mutect2, varscan2
- RPS2 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 15/125 reads (12%) | catalogued as COSV51910120, COSV51910970; called by muse, varscan2
- RXFP1 | c.1672G>T p.G558C | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57050806; called by muse, mutect2, varscan2
- SELENOH | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1269855249; called by muse, mutect2, varscan2
- SEMA3E | c.245G>T p.S82I | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.309); catalogued as COSV57092670; called by muse, mutect2, varscan2
- SEMA4F | c.749T>C p.F250S | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60283531; called by muse, varscan2
- SETDB1 | c.1226T>C p.L409P | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as COSV54984020; called by muse, mutect2, varscan2
- SF3A3 | c.1170+1G>C p.X390_splice | Splice Site (SNP) | VAF 65/442 reads (15%) | catalogued as COSV65955906; called by muse, mutect2, varscan2
- SHPRH | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 91/263 reads (35%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.305); catalogued as COSV51613110; called by muse, mutect2, varscan2
- SIRT3 | c.649C>A p.H217N | Missense Mutation (SNP) | VAF 80/556 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.348); catalogued as COSV61501117; called by muse, mutect2, varscan2
- SLC12A1 | c.1123A>T p.T375S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV57709879; called by muse, mutect2, varscan2
- SLC26A7 | c.761A>C p.K254T | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV52594748; called by muse, mutect2, varscan2
- SLC7A10 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs375602222; called by muse, mutect2, varscan2
- SLC9A7 | c.1567A>G p.I523V | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV60380557; called by muse, mutect2, varscan2
- SLX4 | c.2518G>C p.E840Q | Missense Mutation (SNP) | VAF 99/167 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV53563225, COSV53564626; called by muse, mutect2, varscan2
- SOGA3 | c.2488G>C p.D830H | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64106844; called by muse, mutect2, varscan2
- SPAG16 | c.1298A>T p.E433V | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.855); catalogued as COSV59097269; called by muse, mutect2, varscan2
- SYNE1 | c.19982A>G p.Q6661R (on ENST00000367255 / NM_182961.4; = p.Q6590R on NM_033071.3) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV54998164; called by muse, mutect2, varscan2
- SYNE2 | c.3412A>G p.T1138A | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV59952957; called by muse, mutect2, varscan2
- TAF1L | c.4352A>G p.E1451G | Missense Mutation (SNP) | VAF 87/365 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV54262814; called by muse, mutect2, varscan2
- TDRD5 | c.2921C>A p.P974H | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54243920; called by muse, mutect2, varscan2
- TECPR2 | c.2813C>T p.S938F | Missense Mutation (SNP) | VAF 62/97 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV63970971; called by muse, mutect2, varscan2
- TECTA | c.3284G>T p.R1095L | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.815); catalogued as rs771933470, COSV50716628, COSV99881136; called by muse, mutect2, varscan2
- TLE3 | c.2024C>A p.A675D | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58170051; called by muse, mutect2, varscan2
- TMEM131 | c.1654A>G p.I552V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.401); catalogued as rs773200720, COSV51777232; called by mutect2, varscan2
- TMEM18 | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 82/167 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as rs201517976; called by muse, mutect2, varscan2
- TNRC18 | c.7355G>A p.R2452Q | Missense Mutation (SNP) | VAF 89/135 reads (66%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs777475021, COSV60307859; called by muse, mutect2, varscan2
- TOMM70 | c.467A>G p.Y156C | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52523621; called by muse, mutect2, varscan2
- TP53 | c.404del p.C135Sfs*35 | Frame Shift Del (DEL) | VAF 65/164 reads (40%) | catalogued as COSV52675774, COSV52680475, COSV52702460, COSV53452020; called by mutect2, varscan2
- TRMT10C | c.619T>G p.F207V | Missense Mutation (SNP) | VAF 28/345 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59306008; called by muse, mutect2
- TTN | c.100055C>T p.T33352M (on ENST00000591111; = p.T25928M on NM_003319.4) | Missense Mutation (SNP) | VAF 40/128 reads (31%) | PolyPhen benign (0.003); catalogued as rs368945564, COSV60067083; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.70856A>C p.Q23619P (on ENST00000591111; = p.Q16195P on NM_003319.4) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | PolyPhen possibly damaging (0.732); catalogued as COSV60104076; called by muse, mutect2, varscan2
- TTN | c.43132G>A p.E14378K (on ENST00000591111; = p.E6954K on NM_003319.4) | Missense Mutation (SNP) | VAF 11/150 reads (7%) | PolyPhen possibly damaging (0.587); catalogued as rs758399903, COSV60103369; ClinVar: benign / uncertain significance; called by muse, mutect2
- UBXN11 | c.1417C>T p.R473* (on ENST00000374221 / NM_183008.2; = p.R440* on NM_145345.2) | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as rs746374879, COSV53326509, COSV53329804; called by muse, varscan2
- UGT3A2 | c.430G>T p.V144F | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as COSV56930943; called by muse, mutect2, varscan2
- ULK4 | c.210C>A p.H70Q | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57210561; called by muse, mutect2, varscan2
- USH2A | c.4687C>A p.P1563T | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV56371300; called by muse, mutect2, varscan2
- UTY | c.3846G>T p.E1282D | Missense Mutation (SNP) | VAF 59/86 reads (69%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as COSV58870127; called by muse, mutect2, varscan2
- VCPIP1 | c.3188G>T p.S1063I | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV60047614; called by muse, mutect2
- WDR62 | c.391-2A>G p.X131_splice | Splice Site (SNP) | VAF 28/91 reads (31%) | catalogued as COSV54335495; called by muse, mutect2, varscan2
- WDR75 | c.2028A>C p.K676N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.582); catalogued as COSV59105764; called by muse, mutect2, varscan2
- XPA | c.16G>T p.G6W | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.186); catalogued as rs200218050, COSV64305250, COSV64305306; called by muse, mutect2, varscan2
- ZDHHC14 | c.473A>G p.N158S | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as COSV58194509; called by muse, mutect2, varscan2
- ZFHX4 | c.8299C>A p.L2767I | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.882); catalogued as COSV50893292; called by muse, mutect2, varscan2
- ZFHX4 | c.9347C>A p.S3116Y | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV50726488, COSV50893972, COSV51488364; called by muse, mutect2, varscan2
- ZNF449 | c.830dup p.E278Rfs*23 | Frame Shift Ins (INS) | VAF 13/84 reads (15%) | catalogued as rs781874073; called by mutect2, varscan2
- ZNF479 | c.149G>T p.R50I | Missense Mutation (SNP) | VAF 123/529 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58639221; called by muse, mutect2, varscan2
- ZNF496 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV54177905; called by muse, mutect2, varscan2
- ZNF560 | c.1840G>C p.D614H | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.749); catalogued as COSV56868286; called by muse, mutect2, varscan2
- ZNF570 | c.1459C>G p.Q487E | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.475); catalogued as COSV57579303; called by muse, mutect2, varscan2
- ZNF608 | c.3781G>C p.D1261H | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV60438273; called by muse, mutect2, varscan2
- ZNF765 | c.1406A>G p.N469S | Missense Mutation (SNP) | VAF 73/261 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.902); catalogued as rs761063655, COSV67182673; called by muse, mutect2, varscan2
- ZPLD1 | c.614C>G p.P205R (on ENST00000466937 / NM_001329788.1; = p.P221R on NM_175056.2) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100083556, COSV60353999; called by muse, mutect2, varscan2
- ZSCAN21 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 144/620 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.548); catalogued as rs765252660, COSV52849592; called by muse, mutect2, varscan2
- AKAP6 | c.3115G>A p.D1039N | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- APOBEC3D | c.326G>T p.C109F | Missense Mutation (SNP) | VAF 21/272 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- ATP1A2 | c.739T>C p.C247R | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.313); called by mutect2, varscan2
- CBLC | c.915C>T p.G305= | Splice Region (SNP) | VAF 122/301 reads (41%) | called by muse, mutect2, varscan2
- CCDC6 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.6); called by muse, mutect2
- CHMP7 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 49/456 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- COPG1 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 258/950 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2
- DOCK6 | c.4080G>T p.W1360C | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2
- FLG2 | c.3985C>T p.H1329Y | Missense Mutation (SNP) | VAF 52/462 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.396); called by muse, mutect2
- GCLC | c.1560G>A p.M520I (on ENST00000643939; = p.M518I on NM_001498.4) | Missense Mutation (SNP) | VAF 54/291 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- GIMAP1 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2, varscan2
- GLCE | c.1226G>T p.S409I | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- IGKV2D-30 | c.137G>C p.S46T | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- MX1 | c.1345G>C p.V449L | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.645); called by mutect2, varscan2
- NCOA6 | c.384G>T p.Q128H | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR5V1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 22/857 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.913); called by muse, mutect2
- PAIP2B | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- PFAS | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNKD | c.496G>T p.V166F | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); called by muse, mutect2
- PRDM7 | c.945G>A p.W315* | Nonsense Mutation (SNP) | VAF 18/252 reads (7%) | called by muse, mutect2
- RALGAPA2 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- RC3H1 | c.2768G>A p.W923* | Nonsense Mutation (SNP) | VAF 36/125 reads (29%) | called by muse, mutect2, varscan2
- RTP1 | c.21G>T p.W7C | Missense Mutation (SNP) | VAF 91/827 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPTAN1 | c.3893G>A p.R1298H | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPTBN4 | c.4654C>T p.Q1552* | Nonsense Mutation (SNP) | VAF 46/171 reads (27%) | called by muse, mutect2, varscan2
- SSX2IP | c.1644G>T p.Q548H | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.34); called by muse, mutect2
- TTPA | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2
- UNC13C | c.6490A>G p.S2164G | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP24 | c.2903C>T p.S968F | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- ZNF584 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 27/518 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- ABCC1 | c.1461C>T p.T487= | Silent (SNP) | VAF 59/218 reads (27%) | catalogued as COSV60686976; called by muse, mutect2, varscan2
- ANKRD27 | c.1767G>A p.A589= | Silent (SNP) | VAF 243/581 reads (42%) | catalogued as rs757621638, COSV60131404; called by muse, mutect2, varscan2
- ANXA4 | c.957A>T p.G319= | Silent (SNP) | VAF 58/167 reads (35%) | catalogued as COSV57001912; called by muse, mutect2, varscan2
- ATP7B | c.1921T>C p.L641= | Silent (SNP) | VAF 185/351 reads (53%) | catalogued as COSV54439263; called by muse, mutect2, varscan2
- C1D | c.363C>A p.A121= | Silent (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- C22orf15 | c.312C>T p.Y104= | Silent (SNP) | VAF 18/170 reads (11%) | called by muse, varscan2
- CD1E | c.736C>A p.R246= | Silent (SNP) | VAF 71/226 reads (31%) | catalogued as rs560510473, COSV63769947, COSV63771242; called by muse, mutect2, varscan2
- CDH18 | c.1824G>A p.S608= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as rs767007708, COSV56920030; called by muse, mutect2, varscan2
- CDH22 | c.1860C>T p.A620= | Silent (SNP) | VAF 68/149 reads (46%) | catalogued as COSV64837830; called by muse, mutect2, varscan2
- CDK5RAP3 | c.1503G>A p.L501= | Silent (SNP) | VAF 102/621 reads (16%) | called by muse, mutect2, varscan2
- CNTN3 | c.2526C>T p.Y842= | Silent (SNP) | VAF 106/273 reads (39%) | catalogued as COSV55173159; called by muse, mutect2, varscan2
- COG7 | c.276G>A p.E92= | Silent (SNP) | VAF 16/217 reads (7%) | called by muse, mutect2
- CWF19L1 | c.1098G>T p.L366= | Silent (SNP) | VAF 64/812 reads (8%) | called by muse, mutect2
- DEFB125 | c.462T>A p.T154= | Silent (SNP) | VAF 294/973 reads (30%) | catalogued as COSV66703333; called by muse, varscan2
- DNAH7 | c.435T>C p.D145= | Silent (SNP) | VAF 97/270 reads (36%) | catalogued as rs762094488, COSV56767572; called by muse, varscan2
- EIF2AK3 | c.1251C>A p.V417= | Silent (SNP) | VAF 91/272 reads (33%) | catalogued as COSV57548291, COSV57553130; called by muse, mutect2, varscan2
- EIF3A | c.3873C>T p.D1291= | Silent (SNP) | VAF 77/340 reads (23%) | catalogued as rs774454537, COSV64961656; called by muse, mutect2, varscan2
- FMR1 | c.1449A>G p.R483= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as COSV54424469; called by muse, mutect2, varscan2
- FNIP2 | c.2892C>G p.T964= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV100033120, COSV52440649; called by muse, mutect2, varscan2
- FOXJ3 | c.1497T>G p.S499= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV62362666; called by muse, varscan2
- FRG2C | c.789T>A p.P263= | Silent (SNP) | VAF 20/209 reads (10%) | called by muse, mutect2, varscan2
- IGLV3-12 | c.228C>T p.I76= | Silent (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- INTS1 | c.669C>T p.P223= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs552027973, COSV67176583, COSV67177780; called by muse, mutect2, varscan2
- ITGB8 | c.504C>T p.S168= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as rs200718910; called by muse, mutect2, varscan2
- LARS1 | c.3447G>T p.V1149= (on ENST00000394434 / NM_020117.11; = p.V1122= on NM_016460.3) | Silent (SNP) | VAF 103/250 reads (41%) | catalogued as COSV50977987; called by muse, mutect2, varscan2
- LDHD | c.1203C>A p.I401= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs571838219, COSV55579997, COSV55581053; called by mutect2, varscan2
- LRP2 | c.13296C>T p.L4432= | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as rs187838937, COSV55543645; called by muse, mutect2, varscan2
- LRWD1 | c.423G>A p.L141= | Silent (SNP) | VAF 67/337 reads (20%) | called by muse, varscan2
- MCF2 | c.70T>C p.L24= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV58476896, COSV58478333; called by muse, mutect2, varscan2
- MYPN | c.2583G>A p.A861= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as rs1203254918, COSV62734592; called by muse, mutect2, varscan2
- NAV3 | c.2646C>T p.D882= | Silent (SNP) | VAF 55/101 reads (54%) | catalogued as COSV57083675; called by muse, mutect2, varscan2
- OR2L2 | c.564C>T p.C188= | Silent (SNP) | VAF 92/623 reads (15%) | catalogued as rs1447293549, COSV63553445; called by muse, mutect2, varscan2
- PBDC1 | c.147C>G p.V49= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV64895822; called by muse, mutect2, varscan2
- PDGFRA | c.1605G>A p.L535= | Silent (SNP) | VAF 63/177 reads (36%) | catalogued as COSV57268900; called by muse, mutect2, varscan2
- PKD1 | c.11211G>A p.G3737= (on ENST00000262304 / NM_001009944.3; = p.G3736= on NM_000296.4) | Silent (SNP) | VAF 12/13 reads (92%) | catalogued as COSV51917493; called by muse, mutect2, varscan2
- PSMD2 | c.1935C>T p.D645= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV59530051; called by muse, mutect2
- RASGRF1 | c.813G>C p.R271= | Silent (SNP) | VAF 111/265 reads (42%) | catalogued as COSV69179510; called by muse, mutect2, varscan2
- RPS6KA6 | c.1125G>A p.L375= | Silent (SNP) | VAF 54/87 reads (62%) | catalogued as COSV53120605; called by muse, mutect2, varscan2
- SBF1 | c.3597C>T p.S1199= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs754805260, COSV62367461; called by muse, mutect2, varscan2
- SCN9A | c.1713C>T p.A571= | Silent (SNP) | VAF 36/315 reads (11%) | catalogued as rs200876333, COSV57611883; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SLA | c.201T>G p.G67= (on ENST00000338087 / NM_001045556.3; = p.G107= on NM_006748.4) | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV55078796; called by muse, mutect2, varscan2
- STEAP2 | c.1452G>A p.P484= | Silent (SNP) | VAF 63/121 reads (52%) | catalogued as rs201134508, COSV55288941; called by muse, mutect2, varscan2
- STX5 | c.285C>T p.T95= | Silent (SNP) | VAF 78/177 reads (44%) | catalogued as COSV53679738; called by muse, mutect2, varscan2
- TENM3 | c.1854G>C p.G618= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV69309735; called by muse, mutect2, varscan2
- TGFBRAP1 | c.633G>A p.P211= | Silent (SNP) | VAF 25/277 reads (9%) | catalogued as rs773389653, COSV99305761; called by muse, mutect2
- THSD7A | c.504T>A p.P168= | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as COSV70265657, COSV70269973; called by muse, mutect2, varscan2
- TIPARP | c.1737C>T p.S579= | Silent (SNP) | VAF 107/660 reads (16%) | catalogued as rs781672454; called by muse, mutect2, varscan2
- URGCP | c.879C>T p.F293= (on ENST00000453200 / NM_001077663.3; = p.F284= on NM_017920.4) | Silent (SNP) | VAF 20/101 reads (20%) | called by muse, varscan2
- ZNF311 | c.348G>C p.L116= | Silent (SNP) | VAF 49/190 reads (26%) | catalogued as COSV65853139; called by muse, mutect2, varscan2
- ZNF430 | c.273A>T p.G91= | Silent (SNP) | VAF 81/209 reads (39%) | catalogued as COSV55110160; called by muse, mutect2, varscan2
- ZSWIM4 | c.1281C>T p.A427= | Silent (SNP) | VAF 85/205 reads (41%) | catalogued as rs1238823693, COSV54322403; called by muse, mutect2, varscan2
- COP1 | c.2133+18469G>T | Intron (SNP) | VAF 48/134 reads (36%) | catalogued as COSV100442935, COSV100443102; called by muse, mutect2, varscan2
- GSG1 | c.481+72C>T | Intron (SNP) | VAF 43/153 reads (28%) | catalogued as rs768195450, COSV60970956; called by muse, mutect2, varscan2
- LYSMD4 | c.282+316A>T | Intron (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100230558; called by muse, mutect2, varscan2
- MIR18B | n.28G>C | RNA (SNP) | VAF 32/91 reads (35%) | called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559217 C>A | 5'Flank (SNP) | VAF 76/241 reads (32%) | called by muse, varscan2
- RNU7-174P | chr8:80559218 C>A | 5'Flank (SNP) | VAF 78/245 reads (32%) | catalogued as rs1271623182; called by muse, varscan2
- TRAK1 | c.1963+267G>A | Intron (SNP) | VAF 203/388 reads (52%) | catalogued as COSV100409837; called by muse, mutect2, varscan2
- TTN | c.34265-4184C>A | Intron (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100600122; called by mutect2, varscan2
- VPS28 | c.549-32C>T | Intron (SNP) | VAF 38/93 reads (41%) | catalogued as rs782103607; called by muse, mutect2, varscan2
